FM case AD6358 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/0d412847-5008-4f25-96af-4900a9ec05ef

Female, 52.3 years: Esthesioneuroblastoma (ICD-O-3 9522/3) of the autonomic nervous system; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
